Somatic mutation profile of tumor specimen TCGA-3A-A9I9-01A (aliquot TCGA-3A-A9I9-01A-11D-A38G-08) from TCGA case TCGA-3A-A9I9, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 67.7 years (24,731 days).
Specimen TCGA-3A-A9I9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34f19c4a-681b-43df-9b93-e3d7327be627.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9I9-10A (Blood Derived Normal), aliquot TCGA-3A-A9I9-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e759737d-5819-4f2b-bbac-d753303cf52d

The open-access MAF lists 112 somatic variants for this specimen: 86 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 24, Splice Site 6, Frame Shift Del 3, Nonsense Mutation 3, 3'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 41/361 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 31/247 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs201784880, COSV100750707; called by muse, mutect2, varscan2
- ARHGAP21 | c.2257C>T p.H753Y | Missense Mutation (SNP) | VAF 81/603 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761869137, COSV100256085; called by muse, mutect2, varscan2
- ARHGAP31 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 67/457 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs769289362, COSV99956989; called by muse, mutect2, varscan2
- ATAD2 | c.3196G>C p.D1066H | Missense Mutation (SNP) | VAF 61/420 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV54881585, COSV99784556; called by muse, mutect2, varscan2
- BLCAP | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 41/307 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.91); catalogued as COSV99290040; called by muse, mutect2, varscan2
- BRWD1 | c.4828A>T p.N1610Y | Missense Mutation (SNP) | VAF 36/888 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100313295; called by muse, mutect2
- C16orf70 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 117/858 reads (14%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.998); catalogued as COSV99531287; called by muse, mutect2, varscan2
- C1RL | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 118/739 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1412032309, COSV99864649; called by muse, mutect2, varscan2
- C1S | c.540C>A p.F180L | Missense Mutation (SNP) | VAF 77/563 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs1263347641, COSV100196520; called by muse, varscan2
- CAMSAP3 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 16/335 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371973765, COSV99350515; called by muse, mutect2
- CCDC148 | c.1330A>T p.K444* | Nonsense Mutation (SNP) | VAF 43/363 reads (12%) | catalogued as COSV99320215; called by muse, mutect2, varscan2
- CDC27 | c.2071A>T p.T691S | Missense Mutation (SNP) | VAF 17/517 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99294709; called by muse, mutect2
- CDYL2 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs377184768; called by muse, mutect2, varscan2
- CFH | c.2128T>C p.Y710H | Missense Mutation (SNP) | VAF 72/463 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV100809418; called by muse, mutect2, varscan2
- CLCC1 | c.1646C>T p.P549L (on ENST00000356970 / NM_001377464.1; = p.P499L on NM_015127.5) | Missense Mutation (SNP) | VAF 60/415 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV99915202; called by muse, mutect2, varscan2
- COL4A4 | c.4447G>T p.G1483C | Missense Mutation (SNP) | VAF 47/352 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100306694; called by muse, mutect2, varscan2
- DAGLA | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1565265499, COSV99944295; called by muse, mutect2, varscan2
- DAPP1 | c.625G>C p.D209H | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1272082115, COSV99596803; called by muse, mutect2, varscan2
- DHX36 | c.550T>G p.L184V | Missense Mutation (SNP) | VAF 63/376 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV100273548; called by muse, mutect2, varscan2
- DPP10 | c.989C>A p.T330N | Missense Mutation (SNP) | VAF 40/310 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs1250889908, COSV100063408; called by muse, mutect2, varscan2
- DRD1 | c.396G>C p.E132D | Missense Mutation (SNP) | VAF 64/378 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV101192432; called by muse, mutect2, varscan2
- ELK1 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99902052; called by muse, varscan2
- EML1 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV99214898; called by muse, mutect2, varscan2
- ETV5 | c.826C>G p.P276A | Missense Mutation (SNP) | VAF 26/482 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100112240; called by muse, mutect2
- FAM114A1 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100729273; called by muse, mutect2
- FAM189A2 | c.12+1G>T p.X4_splice | Splice Site (SNP) | VAF 105/738 reads (14%) | catalogued as COSV99974967; called by muse, mutect2, varscan2
- FAM234A | c.1075A>T p.T359S | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.072); catalogued as COSV99395759; called by muse, mutect2, varscan2
- FGF6 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1476081901, COSV57403318; called by muse, mutect2, varscan2
- GPR50 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 107/499 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV99505973; called by muse, mutect2, varscan2
- GRAMD1C | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 88/589 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs199735566; called by muse, mutect2, varscan2
- IBSP | c.211G>T p.G71* | Nonsense Mutation (SNP) | VAF 34/227 reads (15%) | catalogued as COSV99883509; called by muse, mutect2, varscan2
- ITGA4 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 19/453 reads (4%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.656); catalogued as COSV99276153; called by muse, mutect2
- KIAA0100 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 86/609 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV99897876; called by muse, mutect2, varscan2
- KMT2B | c.4948A>G p.T1650A | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1279364009, COSV99719406; called by muse, mutect2, varscan2
- LAMB3 | c.1798G>C p.G600R | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100620272; called by muse, mutect2, varscan2
- LPIN3 | c.335dup p.L113Sfs*15 | Frame Shift Ins (INS) | VAF 26/176 reads (15%) | catalogued as rs756955559; called by mutect2, varscan2
- MAGED2 | c.1646C>A p.T549N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1324069265, COSV99514522; called by muse, mutect2, varscan2
- MAP3K9 | c.2027-1G>C p.X676_splice (on ENST00000554752 / NM_001284230.1; = p.X690_splice on NM_033141.4) | Splice Site (SNP) | VAF 11/79 reads (14%) | catalogued as COSV101173600; called by muse, mutect2, varscan2
- MBTD1 | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 46/405 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1001659600, COSV100899170; called by muse, mutect2, varscan2
- MIA2 | c.2239C>G p.P747A | Missense Mutation (SNP) | VAF 69/494 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV54503048, COSV99697571; called by muse, mutect2, varscan2
- MKI67 | c.6720G>C p.K2240N | Missense Mutation (SNP) | VAF 224/1428 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100896449; called by muse, mutect2, varscan2
- MYH10 | c.3907G>T p.G1303C | Missense Mutation (SNP) | VAF 13/273 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99344986; called by muse, mutect2
- NCAPG | c.2311G>C p.E771Q | Missense Mutation (SNP) | VAF 122/834 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99265887; called by muse, mutect2, varscan2
- NCOA2 | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165276043, COSV101475942; called by muse, mutect2
- NPAP1 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 78/553 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs142710386; called by muse, mutect2, varscan2
- OBSCN | c.22547A>G p.K7516R | Missense Mutation (SNP) | VAF 79/579 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100803210; called by muse, mutect2, varscan2
- OR4B1 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 110/735 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); catalogued as COSV100535580; called by muse, mutect2, varscan2
- PCDHB2 | c.947C>T p.T316I | Missense Mutation (SNP) | VAF 48/372 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as COSV99164986; called by muse, mutect2, varscan2
- PCDHGC5 | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 111/714 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as COSV99339648; called by muse, mutect2, varscan2
- PCYT2 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1259900825, COSV100155498; called by muse, mutect2, varscan2
- PDCD11 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.221); catalogued as COSV100428233; called by muse, mutect2, varscan2
- PDE8B | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1210912764, COSV53744732; called by muse, mutect2, varscan2
- PHOSPHO1 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99865488; called by muse, varscan2
- POLE | c.2629G>C p.V877L | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as COSV100266254; called by muse, varscan2
- PPARGC1B | c.2567C>G p.S856C | Missense Mutation (SNP) | VAF 68/536 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100494678; called by muse, varscan2
- PPP2R1A | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 13/305 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100436234; called by muse, mutect2
- RELN | c.3643G>A p.D1215N | Missense Mutation (SNP) | VAF 190/1471 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1252404801, COSV58995083; called by muse, mutect2, varscan2
- RIPOR1 | c.1840C>G p.H614D (on ENST00000379312 / NM_001193522.2; = p.H610D on NM_024519.4) | Missense Mutation (SNP) | VAF 127/1263 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99243020; called by muse, mutect2, varscan2
- RNF111 | c.1686+1G>C p.X562_splice | Splice Site (SNP) | VAF 43/280 reads (15%) | catalogued as COSV100788993; called by muse, varscan2
- RNF213 | c.10157G>A p.R3386H | Missense Mutation (SNP) | VAF 25/406 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs568680037, COSV60401861; called by muse, mutect2
- RREB1 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.27); catalogued as rs754945001, COSV100619301; called by muse, mutect2, varscan2
- SLC11A1 | c.513G>C p.W171C | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749738584, COSV51918764, COSV99262086; called by muse, mutect2
- SLC11A1 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.363); catalogued as COSV99262094; called by muse, mutect2
- SLC49A3 | c.780C>G p.I260M (on ENST00000404286 / NM_001294341.2; = p.I259M on NM_032219.4) | Missense Mutation (SNP) | VAF 77/556 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100448435; called by muse, mutect2, varscan2
- SOCS5 | c.1451T>C p.L484P | Missense Mutation (SNP) | VAF 95/493 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401047528, COSV100125210; called by muse, mutect2, varscan2
- SYNPO2L | c.1828C>G p.R610G (on ENST00000394810 / NM_001114133.3; = p.R386G on NM_024875.5) | Missense Mutation (SNP) | VAF 51/309 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100866366; called by muse, mutect2, varscan2
- TCTE1 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752830331, COSV65255311; called by muse, mutect2, varscan2
- TECTA | c.4430G>A p.R1477H | Missense Mutation (SNP) | VAF 43/307 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs527976707, COSV50747623; called by muse, mutect2, varscan2
- THBS1 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 50/303 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV99527874; called by muse, mutect2, varscan2
- THRAP3 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 90/518 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV100663302, COSV100663327; called by muse, mutect2, varscan2
- THRAP3 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 92/531 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100663329; called by muse, mutect2, varscan2
- TICRR | c.2719C>T p.Q907* | Nonsense Mutation (SNP) | VAF 30/410 reads (7%) | catalogued as COSV99176335; called by muse, mutect2
- TMEM214 | c.1312G>C p.E438Q | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV99476219; called by muse, mutect2
- TTN | c.7612G>A p.G2538S (on ENST00000591111; = p.G2492S on NM_003319.4) | Missense Mutation (SNP) | VAF 54/349 reads (15%) | PolyPhen possibly damaging (0.797); catalogued as rs932272041, COSV100608899; called by muse, mutect2, varscan2
- UBASH3B | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 76/377 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1043881230, COSV52496993; called by muse, mutect2, varscan2
- WDR3 | c.339G>C p.L113F | Missense Mutation (SNP) | VAF 30/474 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100832083; called by muse, mutect2
- ZNF157 | c.1362A>T p.K454N | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV100998488; called by muse, mutect2, varscan2
- ZNF746 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1198225347, COSV61407566; called by muse, mutect2
- AEBP1 | c.667+2_667+29del p.X223_splice | Splice Site (DEL) | VAF 38/267 reads (14%) | called by mutect2, pindel
- CDKAL1 | c.1364_1383+11del p.X455_splice | Splice Site (DEL) | VAF 16/220 reads (7%) | called by mutect2, pindel
- CFH | c.2479_2483del p.N828Sfs*37 | Frame Shift Del (DEL) | VAF 33/368 reads (9%) | called by mutect2, pindel*
- MUC16 | c.5358_5373del p.R1787Qfs*36 | Frame Shift Del (DEL) | VAF 44/375 reads (12%) | called by mutect2, pindel, varscan2
- PRKCH | c.614-33_627del p.X205_splice | Splice Site (DEL) | VAF 34/388 reads (9%) | called by mutect2, pindel
- WFIKKN2 | c.928_934del p.A310Pfs*18 | Frame Shift Del (DEL) | VAF 28/292 reads (10%) | called by mutect2, pindel
- AMPH | c.858C>T p.P286= | Silent (SNP) | VAF 70/477 reads (15%) | catalogued as rs372756485, COSV57753118; called by muse, mutect2, varscan2
- CACNG2 | c.330G>T p.L110= | Silent (SNP) | VAF 44/289 reads (15%) | catalogued as COSV100268739; called by muse, mutect2, varscan2
- DHX38 | c.2106C>T p.F702= | Silent (SNP) | VAF 71/496 reads (14%) | catalogued as COSV99194290; called by muse, mutect2, varscan2
- DIDO1 | c.4998C>A p.G1666= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as rs1349021711, COSV99825599; called by muse, mutect2, varscan2
- DLGAP1 | c.492C>T p.N164= | Silent (SNP) | VAF 107/539 reads (20%) | catalogued as rs1054343747, COSV59784598; called by muse, mutect2, varscan2
- ENTPD8 | c.903C>A p.L301= | Silent (SNP) | VAF 43/288 reads (15%) | catalogued as COSV100395522; called by muse, mutect2, varscan2
- EPHB4 | c.327G>A p.E109= | Silent (SNP) | VAF 45/395 reads (11%) | catalogued as COSV100639479; called by muse, mutect2, varscan2
- FAT1 | c.11016T>C p.G3672= | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as rs1481876199, COSV101499302; called by muse, mutect2, varscan2
- FBN3 | c.2640T>C p.C880= | Silent (SNP) | VAF 31/226 reads (14%) | catalogued as COSV99560733; called by muse, mutect2, varscan2
- FBXL12 | c.603C>T p.L201= | Silent (SNP) | VAF 32/215 reads (15%) | catalogued as rs746290036, COSV99927943; called by muse, mutect2, varscan2
- KCNK15 | c.201C>A p.L67= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as rs1378352379, COSV100865807; called by muse, mutect2, varscan2
- KRTAP10-9 | c.834C>T p.R278= | Silent (SNP) | VAF 79/443 reads (18%) | catalogued as rs587735240, COSV100553160; called by muse, mutect2, varscan2
- MATN2 | c.1542C>T p.H514= | Silent (SNP) | VAF 66/376 reads (18%) | catalogued as rs1244333147, COSV54722700; called by muse, mutect2, varscan2
- OR2B11 | c.894T>C p.N298= | Silent (SNP) | VAF 235/1351 reads (17%) | catalogued as COSV59509217; called by muse, mutect2, varscan2
- PKD1L1 | c.7944C>A p.P2648= | Silent (SNP) | VAF 37/315 reads (12%) | catalogued as COSV99219370; called by muse, mutect2, varscan2
- PPP4R3B | c.1788G>A p.R596= (on ENST00000616407 / NM_001122964.3; = p.R511= on NM_020463.4) | Silent (SNP) | VAF 61/366 reads (17%) | catalogued as rs1207867911, COSV99701838; called by muse, mutect2, varscan2
- RBSN | c.1584G>A p.R528= | Silent (SNP) | VAF 129/526 reads (25%) | catalogued as COSV99515179; called by muse, mutect2, varscan2
- SCN5A | c.363G>C p.R121= | Silent (SNP) | VAF 48/374 reads (13%) | catalogued as COSV100028339; called by muse, mutect2, varscan2
- SCRN2 | c.514C>T p.L172= | Silent (SNP) | VAF 52/359 reads (14%) | catalogued as COSV99274061; called by muse, mutect2, varscan2
- SHROOM4 | c.3351A>G p.A1117= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV99173323; called by muse, mutect2, varscan2
- SMTNL1 | c.648G>A p.Q216= (on ENST00000399154; = p.Q253= on NM_001105565.2) | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs767702187, COSV101216346; called by muse, mutect2, varscan2
- TPP2 | c.2718T>A p.L906= | Silent (SNP) | VAF 67/573 reads (12%) | catalogued as COSV101060244; called by muse, mutect2, varscan2
- UNC80 | c.720T>C p.I240= | Silent (SNP) | VAF 17/295 reads (6%) | catalogued as rs1196327199, COSV99779301; called by muse, mutect2
- VTI1B | c.672T>G p.V224= | Silent (SNP) | VAF 48/335 reads (14%) | catalogued as COSV99373729; called by muse, mutect2, varscan2
- ACAD9 | c.*215C>T | 3'UTR (SNP) | VAF 35/210 reads (17%) | catalogued as rs1212147483, COSV100459130; called by muse, mutect2, varscan2
- SAMD15 | c.*2G>A | 3'UTR (SNP) | VAF 30/300 reads (10%) | catalogued as rs1308408831, COSV99375442, COSV99375539; called by muse, mutect2
